Somatic mutation profile of tumor specimen TCGA-DD-AAE2-01A (aliquot TCGA-DD-AAE2-01A-11D-A40R-10) from TCGA case TCGA-DD-AAE2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 51.2 years (18,695 days).
Specimen TCGA-DD-AAE2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62df8650-f441-4039-be2b-9bd84d849b66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAE2-10A (Blood Derived Normal), aliquot TCGA-DD-AAE2-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe105c6e-2c91-4c70-a13c-d1c6b1f42c0b

The open-access MAF lists 92 somatic variants for this specimen: 68 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 22, Splice Site 3, Intron 2, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 2, Nonsense Mutation 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4272C>A p.F1424L | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as COSV101330046; called by muse, mutect2, varscan2
- AKR1C2 | c.944dup p.N316* | Frame Shift Ins (INS) | VAF 154/408 reads (38%) | catalogued as rs782634158; called by mutect2, varscan2
- AL136295.1 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs775833062, COSV99938027; called by muse, mutect2, varscan2
- ALOX12B | c.2066A>G p.Y689C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100047121; called by muse, mutect2, varscan2
- ANKRD22 | c.215_218del p.K72Rfs*9 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs768469100; called by mutect2, pindel, varscan2
- ANKRD27 | c.2029G>T p.V677F | Missense Mutation (SNP) | VAF 176/514 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100042820; called by muse, mutect2, varscan2
- ARID4A | c.2118A>C p.L706F | Missense Mutation (SNP) | VAF 152/373 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.146); catalogued as COSV100794266; called by muse, mutect2, varscan2
- ATXN2 | c.1897A>T p.N633Y (on ENST00000550104; = p.N473Y on NM_002973.4) | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.188); catalogued as COSV101112758; called by muse, mutect2
- BRDT | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 166/452 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100740326; called by mutect2, varscan2
- BRINP2 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64181043; called by muse, mutect2, varscan2
- C2CD3 | c.1787A>T p.K596M | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100486712; called by muse, mutect2, varscan2
- CALML6 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100205560; called by muse, mutect2, varscan2
- CAPRIN2 | c.2849T>G p.F950C | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99195504; called by muse, mutect2, varscan2
- CATSPERB | c.322A>C p.I108L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99831289; called by muse, mutect2, varscan2
- CC2D2A | c.202C>G p.P68A (on ENST00000424120 / NM_001378615.1; = p.A103G on NM_020785.2) | Missense Mutation (SNP) | VAF 113/328 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV101052782; called by muse, mutect2, varscan2
- CDC25C | c.666C>A p.N222K | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV100086711; called by muse, mutect2, varscan2
- CDH11 | c.645T>A p.G215= | Splice Region (SNP) | VAF 49/123 reads (40%) | catalogued as COSV99218421; called by muse, mutect2, varscan2
- CDH13 | c.1133del p.G378Efs*6 | Frame Shift Del (DEL) | VAF 53/157 reads (34%) | catalogued as COSV99230837; called by mutect2, pindel, varscan2
- CHP1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100587080; called by muse, mutect2, varscan2
- CHRNA7 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 70/371 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs761782025, COSV100181219; called by muse, varscan2
- CNTLN | c.3062A>G p.H1021R | Missense Mutation (SNP) | VAF 109/263 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as rs1268183988, COSV99264138; called by muse, mutect2, varscan2
- CNTN5 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99676934; called by muse, mutect2, varscan2
- COG5 | c.2399T>A p.L800H (on ENST00000347053 / NM_001379512.1; = p.L821H on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99753305; called by muse, varscan2
- COL11A1 | c.671T>C p.L224S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100616581; called by muse, mutect2
- COL14A1 | c.1715C>A p.A572E | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV52867245, COSV99919316; called by muse, varscan2
- CYP3A5 | c.1290A>G p.I430M | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV99769792; called by muse, mutect2, varscan2
- DAGLA | c.2797C>G p.L933V | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV99944387; called by muse, mutect2, varscan2
- EPB41L3 | c.2084C>A p.T695K | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100549187; called by muse, mutect2, varscan2
- FARP1 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV100130708; called by muse, mutect2, varscan2
- FMN2 | c.3220A>T p.I1074L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100145106; called by muse, mutect2, varscan2
- G6PC | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM990607, COSV99520838; called by muse, mutect2, varscan2
- GALNT7 | c.1149-2A>T p.X383_splice | Splice Site (SNP) | VAF 37/99 reads (37%) | catalogued as COSV99397391; called by muse, mutect2, varscan2
- GASK1B | c.1392C>G p.H464Q | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.497); catalogued as COSV99647623; called by muse, mutect2, varscan2
- GCN1 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV100325262; called by muse, mutect2, varscan2
- GLYR1 | c.1351A>G p.I451V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs760748474, COSV58926659; called by muse, mutect2, varscan2
- HSD17B6 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100444345; called by muse, mutect2, varscan2
- HUWE1 | c.504G>A p.E168= | Splice Region (SNP) | VAF 28/36 reads (78%) | catalogued as COSV99472389, COSV99473778; called by muse, mutect2, varscan2
- IGSF10 | c.5068G>A p.D1690N | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); catalogued as COSV56786148, COSV99180024; called by muse, mutect2, varscan2
- INSYN2A | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs952293347, COSV99729752; called by muse, mutect2, varscan2
- ITGB4 | c.2635C>A p.Q879K | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99564022; called by muse, mutect2, varscan2
- KIAA1549 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as rs766782097, COSV54306797; called by muse, mutect2, varscan2
- KIF1B | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1171875422, COSV99823309; called by muse, mutect2, varscan2
- KRT5 | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 512/1352 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52860097, COSV52863141; called by muse, mutect2, varscan2
- MAGEB2 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 71/85 reads (84%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV100975666, COSV66781064; called by muse, mutect2, varscan2
- MAPKAPK5 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101612889; called by muse, mutect2, varscan2
- MAST4 | c.803G>C p.S268T (on ENST00000403625 / NM_001164664.2; = p.S79T on NM_015183.3) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99844232; called by muse, mutect2, varscan2
- MINDY1 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV100385415; called by muse, mutect2
- MYO3A | c.1254G>A p.M418I | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99779724; called by muse, mutect2
- MYT1L | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101220779, COSV67732922; called by muse, mutect2, varscan2
- PCDHB10 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.331); catalogued as COSV99504320; called by muse, mutect2, varscan2
- PCDHGA10 | c.1954G>T p.D652Y | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99538475, COSV99544195; called by muse, mutect2
- PHF3 | c.1988T>A p.L663Q | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100013370; called by muse, mutect2, varscan2
- RALGAPA1 | c.6104-1G>T p.X2035_splice | Splice Site (SNP) | VAF 29/65 reads (45%) | catalogued as COSV99354788; called by muse, mutect2, varscan2
- RTL6 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100373775; called by muse, mutect2, varscan2
- SCN1A | c.3593A>C p.E1198A (on ENST00000303395 / NM_001202435.3; = p.E1187A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100320461; called by muse, mutect2, varscan2
- SCN5A | c.747G>C p.K249N | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV100348405; called by muse, mutect2, varscan2
- SIGLEC6 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV100585262, COSV100585397; called by muse, mutect2, varscan2
- SLC35E1 | c.1233G>T p.*411Yext*27 | Nonstop Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as rs1393300747, COSV101290775; called by muse, mutect2
- SMAD5 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as rs991396564, COSV101548126; called by muse, mutect2, varscan2
- STRC | c.643T>A p.F215I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV101405419; called by mutect2, varscan2
- TBPL2 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV99905412; called by muse, mutect2
- TRIP11 | c.4181A>T p.E1394V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99970700; called by muse, mutect2, varscan2
- TUSC3 | c.372C>G p.N124K | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.304); catalogued as rs779451208, COSV101141532; called by muse, mutect2, varscan2
- VKORC1L1 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as COSV100663214; called by muse, mutect2, varscan2
- WNT9A | c.584T>G p.V195G | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV99688229; called by muse, mutect2, varscan2
- PACC1 | c.846dup p.V283Cfs*4 | Frame Shift Ins (INS) | VAF 66/225 reads (29%) | called by mutect2, pindel, varscan2
- PTEN | c.694_699del p.T232_R233del | In Frame Del (DEL) | VAF 30/70 reads (43%) | called by mutect2, pindel, varscan2
- THOP1 | c.1456-35_1458del p.X486_splice | Splice Site (DEL) | VAF 32/106 reads (30%) | called by mutect2, pindel
- ADAD1 | c.75A>T p.P25= | Silent (SNP) | VAF 78/186 reads (42%) | catalogued as COSV99635656; called by muse, mutect2, varscan2
- ADAD1 | c.492A>G p.Q164= | Silent (SNP) | VAF 87/216 reads (40%) | catalogued as COSV99635659; called by muse, mutect2, varscan2
- ADM2 | c.319C>A p.R107= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as COSV99326889; called by muse, mutect2, varscan2
- BBS12 | c.951T>A p.T317= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as COSV100044947; called by muse, mutect2, varscan2
- CRB1 | c.690C>T p.S230= | Silent (SNP) | VAF 49/75 reads (65%) | catalogued as COSV100958887; called by muse, mutect2, varscan2
- CREBZF | c.195C>T p.A65= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs775347674, COSV99476275; called by muse, mutect2, varscan2
- CWF19L1 | c.1551C>T p.D517= | Silent (SNP) | VAF 60/101 reads (59%) | catalogued as rs142671230; called by muse, mutect2, varscan2
- EIF1 | c.309T>C p.A103= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV100179518; called by muse, mutect2, varscan2
- EIF2B3 | c.789C>T p.I263= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV100838953; called by muse, mutect2, varscan2
- EPDR1 | c.504A>T p.T168= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV99554419; called by muse, mutect2, varscan2
- FASN | c.6777C>T p.S2259= | Silent (SNP) | VAF 44/173 reads (25%) | catalogued as COSV100147807; called by muse, mutect2, varscan2
- GYG1 | c.411C>T p.F137= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as rs937188326, COSV99936841; called by muse, mutect2
- KRTAP13-2 | c.504A>T p.S168= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV101299637; called by muse, mutect2, varscan2
- LILRA1 | c.633C>A p.P211= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV99251912; called by muse, mutect2, varscan2
- NUCB1 | c.234G>A p.E78= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs762061317, COSV99617883; called by muse, mutect2, varscan2
- OBSCN | c.16755C>T p.I5585= | Silent (SNP) | VAF 84/215 reads (39%) | catalogued as COSV99478181; called by muse, mutect2, varscan2
- PSMC3 | c.1029C>T p.L343= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100099532; called by muse, mutect2, varscan2
- PTPRK | c.846T>C p.N282= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as COSV100949594, COSV63887921; called by muse, mutect2, varscan2
- TENT5B | c.336C>T p.S112= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as COSV100006631; called by muse, mutect2, varscan2
- TSEN34 | c.141C>T p.G47= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs908424228, COSV99824826; called by muse, mutect2, varscan2
- TTPAL | c.108A>T p.T36= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as COSV52829064; called by muse, mutect2, varscan2
- WSCD2 | c.393C>A p.I131= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV54580168, COSV54593301; called by muse, mutect2, varscan2
- COL11A1 | c.2557-170G>T | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as rs867023843; called by muse, mutect2, varscan2
- PISD | c.322-1951del | Intron (DEL) | VAF 45/133 reads (34%) | called by mutect2, pindel, varscan2
